Somatic mutation profile of tumor specimen 0DG0G9 from CCDI case PBBSKD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,907 days).
Specimen 0DG0G9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2770f51f-23c2-4e53-82e1-6a5635532cfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFYPK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dff0ef00-e7e4-4497-af52-648677a14747

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Intron 8, Silent 6, Nonsense Mutation 4, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 244/803 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AIFM3 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 475/977 reads (49%) | catalogued as rs201655926; called by muse, mutect2, varscan2
- DMD | c.4079G>A p.R1360K | Missense Mutation (SNP) | VAF 241/474 reads (51%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.712); catalogued as COSV63756159; called by muse, mutect2, varscan2
- DPH5 | c.764C>T p.T255I | Missense Mutation (SNP) | VAF 394/966 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1404323723; called by muse, mutect2, varscan2
- EPYC | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 417/977 reads (43%) | catalogued as rs779578980, COSV53799693; called by muse, mutect2, varscan2
- FAM9B | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 110/738 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs779744265, COSV100511065; called by muse, mutect2, varscan2
- PIBF1 | c.1152C>G p.I384M | Missense Mutation (SNP) | VAF 50/782 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58327733; called by muse, mutect2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 1254/1335 reads (94%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- WNT11 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 551/722 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs200521278; called by muse, mutect2, varscan2
- WWC3 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 225/667 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs745549559; called by muse, mutect2, varscan2
- ADPRHL1 | c.3713A>G p.H1238R | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.254); called by muse, mutect2
- AGBL5 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 510/1100 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ARHGAP6 | c.1498C>A p.Q500K | Missense Mutation (SNP) | VAF 248/764 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- BRWD3 | c.2895A>G p.I965M | Missense Mutation (SNP) | VAF 275/589 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CALU | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 46/636 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CCPG1 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 148/380 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 191/1159 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLD3 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 416/1457 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RANBP2 | c.3088C>A p.P1030T | Missense Mutation (SNP) | VAF 362/836 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX10 | c.568_569del p.C190Pfs*90 | Frame Shift Del (DEL) | VAF 269/556 reads (48%) | called by mutect2, varscan2
- SP100 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 198/889 reads (22%) | called by muse, mutect2, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 18/602 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- ARHGEF10L | c.2889T>C p.P963= | Silent (SNP) | VAF 170/717 reads (24%) | called by muse, mutect2, varscan2
- KRT2 | c.1899C>T p.S633= | Silent (SNP) | VAF 104/978 reads (11%) | catalogued as rs553228747; called by muse, mutect2, varscan2
- MUC5AC | c.2766C>T p.N922= | Silent (SNP) | VAF 40/1418 reads (3%) | catalogued as rs1278843106; called by muse, mutect2
- OR5A1 | c.546C>T p.C182= | Silent (SNP) | VAF 170/411 reads (41%) | catalogued as rs1032680539, COSV100118347, COSV57375591; called by muse, mutect2, varscan2
- SLFN11 | c.1032C>T p.T344= | Silent (SNP) | VAF 326/794 reads (41%) | catalogued as rs746027644, COSV100390732, COSV57700661; called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 18/596 reads (3%) | catalogued as rs1267156464; called by muse, mutect2
- CATSPERG | c.1316-26T>G | Intron (SNP) | VAF 45/216 reads (21%) | called by muse, mutect2, varscan2
- CBX2 | c.288+51C>T | Intron (SNP) | VAF 251/630 reads (40%) | catalogued as rs145903665; called by muse, mutect2, varscan2
- CEP63 | chr3:134486134 A>T | 5'Flank (SNP) | VAF 231/506 reads (46%) | called by muse, mutect2, varscan2
- CFLAR | c.606+1026T>A | Intron (SNP) | VAF 28/512 reads (5%) | called by muse, mutect2
- EDN3 | c.52+93C>A | Intron (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- FXR2 | c.1020+20G>T | Intron (SNP) | VAF 30/563 reads (5%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- NSD3 | c.2612-45G>A | Intron (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- PDZD2 | c.1666-50A>G | Intron (SNP) | VAF 128/239 reads (54%) | called by muse, mutect2, varscan2
